Gene-level copy-number profile of tumor specimen TCGA-ER-A19E-06A from TCGA case TCGA-ER-A19E, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 36.5 years (13,331 days).
Specimen TCGA-ER-A19E-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.4345aea5-ffcf-460a-b915-b74e8056c230.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4a1ffc76-0a61-45fa-ba00-5835416bba63

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,123; copy number 2: 20,298; copy number 3: 20,742; copy number 4: 12,433; copy number 5: 732; copy number 6: 1,955; copy number 7: 700; copy number 8: 372; copy number 9: 53; copy number 10: 16; copy number 11: 147; copy number 12: 165; copy number 13: 3; copy number 15: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19E-06A-11D-A191-01): tumor purity 0.72, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:232,917,235–232,918,018, 1 gene: AL122003.1.
- chr6:127,968,785–128,520,616, 1 gene (within-gene range 0–2): PTPRK.
- chr6:128,500,527–128,761,808, 5 genes: AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA.
- chr6:128,928,995–128,929,988, 1 gene: MESTP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,524 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:98,706,236–99,018,562, 9 genes, copy number 9: ST3GAL6-AS1, ST3GAL6, PDLIM1P4, DCBLD2, RNU6-26P, AC091212.1, RNU6-1263P, LINC00973, U7.
- chr6:42,499,710–42,693,505, 3 genes, copy number 10 (within-gene range 6–10): AL591473.1, UBR2, RNU6-890P.
- chr6:45,328,157–45,664,349, 1 gene, copy number 7 (within-gene range 6–7): RUNX2.
- chr6:45,573,346–48,952,781, 42 genes, copy number 7: RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1.
- chr6:57,855,891–58,438,364, 13 genes, copy number 10: AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr7:15,736,373–17,558,909, 29 genes, copy number 7 (within-gene range 6–7): AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1.
- chr7:35,496,021–63,385,789, 487 genes, copy number 7–15 (broad region; genes not listed).
- chr7:101,815,904–102,283,958, 1 gene, copy number 7 (within-gene range 4–7): CUX1.
- chr7:101,960,116–104,208,047, 66 genes, copy number 7 (broad region; genes not listed).
- chr7:106,372,251–109,660,802, 47 genes, copy number 7 (within-gene range 3–7): AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1.
- chr7:109,998,434–142,106,747, 528 genes, copy number 7–15 (within-gene range 5–15) (broad region; genes not listed).
- chr7:143,935,166–158,591,696, 287 genes, copy number 8–15 (broad region; genes not listed).
- chr20:51,386,957–52,204,308, 11 genes, copy number 7 (within-gene range 4–7): NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.

Autosomal genes at a single copy (total copy number 1): 651. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
